Somatic mutation profile of tumor specimen HCM-WCMC-0945-C54-01A (aliquot HCM-WCMC-0945-C54-01A-11D-A937-36) from HCMI case HCM-WCMC-0945-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 65.0 years (23,744 days).
Specimen HCM-WCMC-0945-C54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7beb3f9e-f74b-416c-add4-f6059644af8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0945-C54-11A (Slides), aliquot HCM-WCMC-0945-C54-11A-15D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21992367-17a4-449d-a9fb-e03f33d26af6

The open-access MAF lists 344 somatic variants for this specimen: 242 protein-altering or splice-affecting, 90 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 90, Frame Shift Del 36, Nonsense Mutation 11, Frame Shift Ins 8, Intron 7, 3'UTR 2, Splice Region 2, 5'UTR 2, In Frame Del 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 344/816 reads (42%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 199/447 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 259/598 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2300_2308dup p.A767_V769dup | In Frame Ins (INS) | VAF 189/456 reads (41%) | hotspot (GDC flag); catalogued as rs727504263; ClinVar: drug response; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 69/358 reads (19%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 266/544 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 134/309 reads (43%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 194/401 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 140/298 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779530981, CM033666, COSV64288954, COSV64292660; called by mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 198/448 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- ADGRA2 | c.145del p.E49Sfs*6 | Frame Shift Del (DEL) | VAF 358/768 reads (47%) | catalogued as rs1348306197; called by mutect2, varscan2
- ADGRB3 | c.2939G>T p.R980I | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53260222; called by muse, mutect2, varscan2
- ARHGAP32 | c.3926C>T p.P1309L (on ENST00000310343 / NM_001378025.1; = p.P960L on NM_014715.4) | Missense Mutation (SNP) | VAF 239/516 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.162); catalogued as rs764707491; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 181/396 reads (46%) | catalogued as rs771098505; called by mutect2, varscan2
- BHLHA15 | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 75/678 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377018035, COSV99807679; called by muse, varscan2
- BLVRA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 266/543 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs138692014; called by muse, mutect2, varscan2
- C3 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 261/566 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs945676974, COSV55573557; called by muse, mutect2, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, varscan2
- CLEC1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 230/545 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.208); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- CLSTN3 | c.526del p.Q176Sfs*43 | Frame Shift Del (DEL) | VAF 181/436 reads (42%) | catalogued as rs1565648977, COSV56937112; called by mutect2, varscan2
- CNGA3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 178/362 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs77733216, COSV55625289; called by muse, mutect2, varscan2
- CPA3 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 235/578 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1480716038; called by muse, mutect2
- CUBN | c.6157C>T p.L2053F | Missense Mutation (SNP) | VAF 182/458 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs751834059, COSV100911747, COSV64726423; called by muse, mutect2, varscan2
- CUL3 | c.1358del p.N453Tfs*2 | Frame Shift Del (DEL) | VAF 34/316 reads (11%) | catalogued as rs1366667901; called by mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | catalogued as rs772257590; called by mutect2, varscan2
- DCAF17 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 208/411 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs1464028164; called by muse, mutect2, varscan2
- DCAF8L2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 277/655 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV101446081; called by muse, mutect2, varscan2
- DDX3X | c.826G>C p.E276Q (on ENST00000399959; = p.E277Q on NM_001356.5) | Missense Mutation (SNP) | VAF 195/477 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864271; called by muse, mutect2, varscan2
- DENND11 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 341/767 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs369765513; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 256/634 reads (40%) | catalogued as COSV58330771; called by mutect2, varscan2
- DUSP13 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1476389248, COSV57815315; called by muse, mutect2
- EML2 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 175/434 reads (40%) | catalogued as rs35928591, COSV55598462; called by muse, mutect2, varscan2
- ENOX2 | c.361C>T p.R121* (on ENST00000338144 / NM_001382520.1; = p.R92* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 258/574 reads (45%) | catalogued as rs778865428; called by muse, mutect2, varscan2
- ENTPD6 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 196/391 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs747725682; called by muse, mutect2, varscan2
- EPHA2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 292/662 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754639981, COSV64452591; called by muse, mutect2, varscan2
- EPN1 | c.1680del p.M561* (on ENST00000270460 / NM_001321263.1; = p.M535* on NM_013333.3) | Frame Shift Del (DEL) | VAF 310/660 reads (47%) | catalogued as rs1306515040; called by mutect2, varscan2
- ERBB3 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 243/560 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57253288; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 256/660 reads (39%) | catalogued as rs780487406; called by mutect2, varscan2
- EXOSC10 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 206/460 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1188088244, COSV99061299; called by muse, mutect2, varscan2
- EXOSC8 | c.117C>T p.I39= | Splice Region (SNP) | VAF 62/336 reads (18%) | catalogued as rs1369374009; called by muse, mutect2, varscan2
- FAM160B2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 181/362 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs933078380; called by muse, mutect2, varscan2
- FBXO30 | c.1661G>T p.R554M | Missense Mutation (SNP) | VAF 260/568 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395452; called by muse, mutect2, varscan2
- FLNA | c.4343C>T p.A1448V | Missense Mutation (SNP) | VAF 310/674 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201886752; called by muse, mutect2, varscan2
- FN1 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 321/663 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs370103949; called by muse, mutect2, varscan2
- FOXA1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 311/693 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs752702606; called by muse, mutect2, varscan2
- FOXD1 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 231/553 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.24); catalogued as rs1454007948, COSV100197620; called by muse, mutect2, varscan2
- FUT4 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 290/627 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1253711275; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 254/812 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1230580971, COSV101417052, COSV71180979; called by muse, mutect2, varscan2
- GPR179 | c.2163G>A p.M721I (on ENST00000621958; = p.M720I on NM_001004334.4) | Missense Mutation (SNP) | VAF 438/972 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1285711228; called by muse, mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 100/229 reads (44%) | catalogued as rs747918697; called by mutect2, varscan2
- HCN1 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 245/538 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57494297; called by muse, mutect2, varscan2
- HSPA8 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 185/395 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV57083414; called by muse, mutect2, varscan2
- INTS12 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 164/380 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as rs1466709231, COSV100415763; called by muse, mutect2, varscan2
- ITLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 209/468 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs912358230, COSV63537517; called by muse, mutect2, varscan2
- KIF26B | c.4319C>T p.P1440L | Missense Mutation (SNP) | VAF 441/923 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272543569, COSV63649568; called by muse, mutect2, varscan2
- KIF2B | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 265/550 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV52127037, COSV52134855; called by muse, mutect2, varscan2
- KPTN | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54549508; called by muse, mutect2
- LMCD1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440912941, COSV50088926; called by muse, mutect2
- LMOD3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 282/627 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778824655, COSV70456816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP1 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 308/658 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867925414, COSV56799253; called by muse, varscan2
- LTBP2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 327/766 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781644874; called by muse, mutect2, varscan2
- MACF1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 170/424 reads (40%) | catalogued as COSV57102933, COSV57103434; called by muse, mutect2, varscan2
- MACROD2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 153/340 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV54027769; called by muse, mutect2, varscan2
- MAPRE2 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV55817203; called by muse, mutect2, varscan2
- MCM4 | c.1553A>G p.Q518R | Missense Mutation (SNP) | VAF 236/504 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs375382737; called by muse, mutect2, varscan2
- MEI4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 244/550 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs1424549035; called by muse, mutect2, varscan2
- MICAL2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 220/478 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773570310; called by muse, varscan2
- MOSPD1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143435005; called by muse, varscan2
- MS4A2 | c.498A>T p.K166N | Missense Mutation (SNP) | VAF 260/526 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1481946030; called by muse, varscan2
- MYT1 | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 334/721 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs759011128, COSV60514422; called by muse, mutect2, varscan2
- NECAB2 | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 218/473 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs770058947; called by muse, mutect2, varscan2
- OR6S1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 290/623 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57839130; called by muse, mutect2, varscan2
- PACS2 | c.252dup p.S85Qfs*57 | Frame Shift Ins (INS) | VAF 183/395 reads (46%) | catalogued as rs782816086; called by mutect2, varscan2
- PCDH19 | c.3110G>T p.R1037M (on ENST00000373034 / NM_001184880.2; = p.R989M on NM_020766.3) | Missense Mutation (SNP) | VAF 357/840 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55270202; called by muse, mutect2, varscan2
- PDE4D | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 195/435 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs867397273; called by muse, mutect2, varscan2
- POLL | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs149081648; called by muse, mutect2, varscan2
- POMT1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 150/389 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292313849; called by muse, mutect2, varscan2
- PPP1R26 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 63/804 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs750002293; called by muse, mutect2
- PRICKLE3 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 391/899 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs370668964; called by muse, varscan2
- PTPRD | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 154/413 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100643981; called by muse, mutect2, varscan2
- PWP2 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 190/262 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764962504; called by muse, mutect2, varscan2
- RALGDS | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 219/473 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.615); catalogued as rs148398301; called by muse, mutect2, varscan2
- RAVER1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 257/575 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776468563, COSV53349496; called by muse, mutect2, varscan2
- RBM15B | c.1608_1610del p.L537del | In Frame Del (DEL) | VAF 246/570 reads (43%) | catalogued as rs1258957852; called by mutect2, varscan2
- RBM19 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 265/582 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs568147769; called by muse, mutect2, varscan2
- RLN1 | c.479del p.K160Rfs*14 | Frame Shift Del (DEL) | VAF 186/400 reads (47%) | catalogued as rs758351039; called by mutect2, varscan2
- RNASE9 | c.616T>C p.*206Qext*5 | Nonstop Mutation (SNP) | VAF 124/318 reads (39%) | catalogued as rs1449285888; called by muse, mutect2
- RNF165 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 310/678 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53972037; called by muse, varscan2
- RPS6KA1 | c.1324A>G p.M442V | Missense Mutation (SNP) | VAF 161/376 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs772096189; called by muse, mutect2, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 324/628 reads (52%) | catalogued as COSV62684236; called by mutect2, varscan2
- SH3PXD2B | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 350/714 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV100288226; called by muse, mutect2, varscan2
- SHANK1 | c.6442C>T p.R2148C | Missense Mutation (SNP) | VAF 213/471 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99521318; called by muse, mutect2, varscan2
- SIN3B | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 163/399 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as COSV56134011; called by muse, mutect2, varscan2
- SLC12A7 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs1187222840; called by muse, mutect2, varscan2
- SLC35A4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 276/618 reads (45%) | catalogued as rs775493102; called by muse, mutect2, varscan2
- SLC37A2 | c.1196del p.G399Afs*24 | Frame Shift Del (DEL) | VAF 192/422 reads (45%) | catalogued as COSV53524083; called by mutect2, varscan2
- SLC5A7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 261/562 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs748755332, COSV50891064; called by muse, mutect2, varscan2
- SMC1A | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 337/692 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782636271; called by muse, mutect2, varscan2
- SMO | c.1464G>A p.V488= | Splice Region (SNP) | VAF 154/351 reads (44%) | catalogued as rs1384472073, COSV50838661; called by muse, mutect2, varscan2
- SMPD4 | c.1768C>T p.R590C (on ENST00000409031 / NM_017951.4; = p.R561C on NM_017751.4) | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752750090, COSV100302457; called by muse, mutect2, varscan2
- SNTG1 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 194/483 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs764565019; called by muse, mutect2, varscan2
- SOX3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 369/835 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65168347; called by muse, mutect2, varscan2
- STK32B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 260/558 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs553561922, COSV51494342; called by muse, mutect2, varscan2
- SUPT5H | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 288/652 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316671406; called by muse, mutect2, varscan2
- SYNPO | c.2026C>T p.Q676* (on ENST00000394243 / NM_001166208.2; = p.Q432* on NM_007286.6) | Nonsense Mutation (SNP) | VAF 381/806 reads (47%) | catalogued as COSV56938757; called by muse, mutect2, varscan2
- TAS2R31 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 346/810 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1283986544, COSV101114746; called by muse, mutect2, varscan2
- TDRD6 | c.2750del p.N917Ifs*2 | Frame Shift Del (DEL) | VAF 178/409 reads (44%) | catalogued as COSV60174471; called by mutect2, varscan2
- TGM2 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 206/440 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs1249287719; called by muse, mutect2
- TIMM17B | c.212dup p.L72Pfs*56 | Frame Shift Ins (INS) | VAF 217/507 reads (43%) | catalogued as rs782500597; called by mutect2, varscan2
- TNRC6B | c.4006T>C p.S1336P (on ENST00000454349 / NM_001162501.2; = p.S1226P on NM_015088.3) | Missense Mutation (SNP) | VAF 292/714 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as rs1244593172; called by muse, mutect2, varscan2
- TOMM40L | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as COSV63467793; called by mutect2, varscan2
- TTN | c.13351G>A p.G4451S (on ENST00000591111; = p.G4405S on NM_003319.4) | Missense Mutation (SNP) | VAF 232/532 reads (44%) | PolyPhen probably damaging (0.962); catalogued as rs727503652; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- UNC80 | c.4381C>T p.H1461Y | Missense Mutation (SNP) | VAF 152/323 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV55904808; called by muse, mutect2, varscan2
- YY1 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 116/249 reads (47%) | catalogued as COSV51764900; called by muse, mutect2, varscan2
- ZAR1L | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 193/414 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs950022307; called by muse, mutect2, varscan2
- ZHX1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 42/759 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs747135351, COSV52876504; called by muse, mutect2
- ZNF37A | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1212177918; called by muse, mutect2, varscan2
- ZNF512B | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 248/536 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs754690373; called by muse, mutect2, varscan2
- ZNF83 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 232/556 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs762225164, COSV99991334; called by muse, mutect2, varscan2
- ZNF835 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 340/736 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1267768322; called by muse, mutect2, varscan2
- AAAS | c.270del p.F90Lfs*4 | Frame Shift Del (DEL) | VAF 169/417 reads (41%) | called by mutect2, varscan2
- ABHD12B | c.857A>G p.D286G (on ENST00000337334 / NM_001206673.2; = p.D209G on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AC244197.3 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 260/580 reads (45%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ADGRA1 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 330/702 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- AMBN | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 24/614 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2
- AMBN | c.823T>G p.Y275D | Missense Mutation (SNP) | VAF 169/448 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD11 | c.574del p.A192Qfs*36 | Frame Shift Del (DEL) | VAF 228/539 reads (42%) | called by mutect2, varscan2
- ANPEP | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 259/632 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AOX1 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.043); called by muse, mutect2
- ARFGAP3 | c.669dup p.G224Rfs*20 | Frame Shift Ins (INS) | VAF 82/220 reads (37%) | called by mutect2, varscan2
- ARHGAP25 | c.1225C>T p.P409S (on ENST00000409202 / NM_001007231.3; = p.P401S on NM_014882.3) | Missense Mutation (SNP) | VAF 209/445 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP29 | c.2364del p.K788Nfs*7 | Frame Shift Del (DEL) | VAF 148/348 reads (43%) | called by mutect2, varscan2
- ARID1B | c.3023A>G p.E1008G | Missense Mutation (SNP) | VAF 182/406 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ARIH1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 318/679 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARMH1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 22/666 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ARX | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 414/889 reads (47%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ASAH2 | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 251/568 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ASS1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 161/361 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATXN7L3 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 331/682 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- BACH2 | c.819dup p.Q274Afs*3 | Frame Shift Ins (INS) | VAF 272/602 reads (45%) | called by mutect2, varscan2
- BRINP1 | c.117T>G p.D39E | Missense Mutation (SNP) | VAF 236/573 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- BRWD3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 161/354 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf38 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 288/635 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.917); called by muse, varscan2
- CACNA1E | c.2600T>G p.L867R | Missense Mutation (SNP) | VAF 330/763 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNG8 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 366/773 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 174/346 reads (50%) | called by mutect2, varscan2
- CCDC196 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 173/360 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CD2AP | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH22 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 248/574 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CHD1L | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- CHTF18 | c.2179dup p.Q727Pfs*59 | Frame Shift Ins (INS) | VAF 140/326 reads (43%) | called by mutect2, varscan2
- CLIC3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 293/697 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CNIH4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 240/524 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CNKSR2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 214/502 reads (43%) | called by muse, varscan2
- COL15A1 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 226/474 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CREB1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 197/423 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSGALNACT2 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CYP21A2 | c.793del p.V265Wfs*26 | Frame Shift Del (DEL) | VAF 100/1000 reads (10%) | called by mutect2, varscan2
- DENND4C | c.5749G>A p.D1917N (on ENST00000434457 / NM_001330640.2; = p.D1868N on NM_017925.7) | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.6352C>T p.R2118* | Nonsense Mutation (SNP) | VAF 215/472 reads (46%) | called by muse, mutect2, varscan2
- EHD1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 41/852 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 185/398 reads (46%) | called by mutect2, varscan2
- FAM193B | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 386/809 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- FBXW7 | c.1791del p.N598Mfs*30 (on ENST00000281708 / NM_001349798.2; = p.N518Mfs*30 on NM_018315.5) | Frame Shift Del (DEL) | VAF 176/418 reads (42%) | called by mutect2, varscan2
- FKBP4 | c.401T>C p.L134S | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRE | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 315/707 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GAGE12H | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 206/1823 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GJA3 | c.771del p.S258Afs*43 | Frame Shift Del (DEL) | VAF 352/751 reads (47%) | called by mutect2, varscan2
- GLP2R | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- GNS | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 346/758 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GPC6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 234/495 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC2 | c.12998T>C p.M4333T | Missense Mutation (SNP) | VAF 238/531 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 301/659 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HPS1 | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 201/469 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HSD3B7 | c.543dup p.L182Afs*16 | Frame Shift Ins (INS) | VAF 221/496 reads (45%) | called by mutect2, varscan2
- IRF6 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 265/565 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0319L | c.1224del p.I409Lfs*43 | Frame Shift Del (DEL) | VAF 169/404 reads (42%) | called by mutect2, varscan2
- KLRC3 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 156/378 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- KMT2A | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 242/525 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT5 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LMNTD2 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 383/848 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- LNX2 | c.1119del p.L374Wfs*8 | Frame Shift Del (DEL) | VAF 241/540 reads (45%) | called by mutect2, varscan2
- LRIG3 | c.1827del p.M610Wfs*25 | Frame Shift Del (DEL) | VAF 226/480 reads (47%) | called by mutect2, varscan2
- LRRC4B | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 352/741 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRRD1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 220/535 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MAP3K15 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 147/335 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2L2 | c.1257dup p.W420Mfs*12 | Frame Shift Ins (INS) | VAF 185/403 reads (46%) | called by mutect2, varscan2
- MEST | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 267/553 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MINDY3 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 137/314 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MORC3 | c.1403del p.K468Rfs*14 | Frame Shift Del (DEL) | VAF 126/298 reads (42%) | called by mutect2, varscan2
- MRTFB | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 220/496 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NFATC2 | c.2654del p.K885Rfs*8 | Frame Shift Del (DEL) | VAF 256/534 reads (48%) | called by mutect2, varscan2
- NKX3-2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 31/868 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2
- NPEPL1 | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 241/552 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 250/550 reads (45%) | called by mutect2, varscan2
- OBSL1 | c.4801C>A p.L1601M | Missense Mutation (SNP) | VAF 294/646 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4D11 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 239/533 reads (45%) | called by muse, mutect2, varscan2
- OR51D1 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 42/730 reads (6%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.53); called by muse, mutect2
- OR7C1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 58/554 reads (10%) | called by mutect2, varscan2
- PCDH17 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 33/678 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIGN | c.620dup p.H209Tfs*24 | Frame Shift Ins (INS) | VAF 89/223 reads (40%) | called by mutect2, varscan2
- PLA2R1 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 151/361 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLXNA4 | c.1943G>A p.S648N | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- POLR2E | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 277/579 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKDC | c.6479A>T p.Y2160F | Missense Mutation (SNP) | VAF 164/389 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PSMB8 | c.414C>G p.Y138* (on ENST00000374882 / NM_148919.4; = p.Y134* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 263/538 reads (49%) | called by muse, mutect2, varscan2
- QSOX1 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 330/697 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SALL2 | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 292/594 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, varscan2
- SHC3 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 307/708 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SIGLEC1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 34/816 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- SIPA1L2 | c.4828G>A p.A1610T | Missense Mutation (SNP) | VAF 157/360 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A7 | c.2153T>C p.L718P | Missense Mutation (SNP) | VAF 430/968 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC25A17 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 142/280 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC29A3 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 280/601 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC52A1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 221/481 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNPH | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 326/688 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SON | c.3447G>C p.L1149F | Missense Mutation (SNP) | VAF 263/633 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPAG1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 225/519 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX11 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 285/638 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SUPT20H | c.271C>T p.L91F (on ENST00000350612 / NM_001014286.3; = p.L92F on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYDE1 | c.1230del p.G411Afs*21 | Frame Shift Del (DEL) | VAF 226/619 reads (37%) | called by mutect2, varscan2
- TAF4B | c.1799del p.N600Ifs*3 | Frame Shift Del (DEL) | VAF 127/305 reads (42%) | called by mutect2, varscan2
- TBC1D24 | c.1505del p.G502Afs*21 (on ENST00000646147 / NM_001199107.2; = p.G496Afs*21 on NM_020705.3) | Frame Shift Del (DEL) | VAF 167/436 reads (38%) | called by mutect2, varscan2
- TCP11L1 | c.1420A>G p.R474G | Missense Mutation (SNP) | VAF 279/592 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TMEM129 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 264/597 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM132D | c.2141A>G p.Q714R | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM38B | c.286del p.C96Afs*5 | Frame Shift Del (DEL) | VAF 138/322 reads (43%) | called by mutect2, varscan2
- TNS1 | c.5131C>A p.L1711I | Missense Mutation (SNP) | VAF 103/658 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TRAT1 | c.50T>G p.L17W | Missense Mutation (SNP) | VAF 236/507 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TTBK1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 186/427 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TTN | c.47063del p.K15688Rfs*20 (on ENST00000591111; = p.K8264Rfs*20 on NM_003319.4) | Frame Shift Del (DEL) | VAF 170/390 reads (44%) | called by mutect2, varscan2
- UBR4 | c.12017C>A p.P4006H | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBR4 | c.2089G>T p.G697* | Nonsense Mutation (SNP) | VAF 181/436 reads (42%) | called by muse, mutect2, varscan2
- UGT2B28 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 178/442 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP53 | c.2959C>T p.Q987* | Nonsense Mutation (SNP) | VAF 240/538 reads (45%) | called by muse, varscan2
- VPS13B | c.8222T>C p.I2741T | Missense Mutation (SNP) | VAF 183/429 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- YTHDC2 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB34 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 267/607 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM1 | c.2968A>G p.I990V | Missense Mutation (SNP) | VAF 22/700 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- ZNF318 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 288/636 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF337 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 226/495 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- ZNF852 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 147/343 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- A3GALT2 | c.576G>A p.A192= | Silent (SNP) | VAF 265/616 reads (43%) | called by muse, mutect2, varscan2
- ABCA2 | c.3066C>T p.C1022= (on ENST00000614293; = p.C992= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 248/526 reads (47%) | catalogued as rs768859234; called by muse, mutect2, varscan2
- ADGRA1 | c.477A>G p.L159= | Silent (SNP) | VAF 134/311 reads (43%) | called by muse, mutect2, varscan2
- ADIPOR2 | c.147T>G p.S49= | Silent (SNP) | VAF 164/416 reads (39%) | called by muse, mutect2, varscan2
- ALX1 | c.174C>T p.R58= | Silent (SNP) | VAF 233/509 reads (46%) | called by muse, mutect2, varscan2
- ANKRD52 | c.1485C>T p.Y495= | Silent (SNP) | VAF 212/473 reads (45%) | catalogued as rs1007884284, COSV57281856; called by muse, varscan2
- AP3M2 | c.918G>A p.E306= | Silent (SNP) | VAF 287/633 reads (45%) | catalogued as rs773844925; called by muse, mutect2, varscan2
- APLNR | c.186C>A p.R62= | Silent (SNP) | VAF 303/615 reads (49%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.1371G>A p.R457= | Silent (SNP) | VAF 162/216 reads (75%) | catalogued as rs1423578342; called by muse, mutect2, varscan2
- C16orf46 | c.642G>C p.L214= | Silent (SNP) | VAF 348/712 reads (49%) | catalogued as COSV55150130; called by muse, mutect2, varscan2
- C5orf34 | c.48A>G p.Q16= | Silent (SNP) | VAF 16/514 reads (3%) | called by muse, mutect2
- CDK5RAP1 | c.732C>T p.S244= | Silent (SNP) | VAF 191/414 reads (46%) | catalogued as rs1169087332; called by muse, mutect2, varscan2
- CECR2 | c.783C>T p.R261= (on ENST00000342247 / NM_001290047.2; = p.R98= on NM_001290046.1) | Silent (SNP) | VAF 256/576 reads (44%) | catalogued as rs766186451, COSV52848326; called by muse, mutect2, varscan2
- CEP85 | c.1908A>G p.S636= | Silent (SNP) | VAF 117/316 reads (37%) | catalogued as rs1300824821; called by muse, mutect2, varscan2
- CFTR | c.1164G>A p.T388= | Silent (SNP) | VAF 139/331 reads (42%) | catalogued as rs1800088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.7935A>T p.A2645= (on ENST00000398510 / NM_001382353.1; = p.A2629= on NM_025134.7) | Silent (SNP) | VAF 213/478 reads (45%) | catalogued as rs1378908463, COSV54608422; called by muse, varscan2
- CNDP2 | c.936G>A p.P312= | Silent (SNP) | VAF 251/533 reads (47%) | catalogued as rs781276053; called by muse, mutect2, varscan2
- CNNM1 | c.2538C>T p.D846= | Silent (SNP) | VAF 158/368 reads (43%) | catalogued as rs116405851; called by muse, mutect2, varscan2
- COL18A1 | c.3351C>T p.L1117= (on ENST00000359759 / NM_130444.3; = p.L882= on NM_030582.4) | Silent (SNP) | VAF 222/512 reads (43%) | called by muse, mutect2, varscan2
- CPED1 | c.1065C>T p.C355= | Silent (SNP) | VAF 130/305 reads (43%) | catalogued as COSV60006478; called by muse, mutect2, varscan2
- CSN2 | c.465G>A p.Q155= | Silent (SNP) | VAF 240/628 reads (38%) | catalogued as rs1327190827; called by muse, varscan2
- DAP | c.201C>T p.D67= | Silent (SNP) | VAF 158/313 reads (50%) | called by muse, mutect2, varscan2
- DICER1 | c.3051T>C p.A1017= | Silent (SNP) | VAF 175/416 reads (42%) | called by muse, mutect2, varscan2
- EMSY | c.1221T>C p.S407= | Silent (SNP) | VAF 35/680 reads (5%) | called by muse, mutect2
- EXT1 | c.1179C>T p.I393= | Silent (SNP) | VAF 134/319 reads (42%) | catalogued as COSV100984117; called by muse, mutect2, varscan2
- FAM131C | c.504G>A p.S168= | Silent (SNP) | VAF 118/562 reads (21%) | catalogued as rs756525734; called by muse, mutect2
- FAM155B | c.36C>T p.D12= | Silent (SNP) | VAF 267/606 reads (44%) | catalogued as COSV52936437; called by muse, varscan2
- FSIP1 | c.1302T>C p.I434= | Silent (SNP) | VAF 183/444 reads (41%) | called by muse, mutect2, varscan2
- FXYD6 | c.204G>A p.K68= | Silent (SNP) | VAF 199/438 reads (45%) | called by muse, mutect2, varscan2
- GAS8 | c.909C>T p.D303= | Silent (SNP) | VAF 180/387 reads (47%) | called by muse, mutect2, varscan2
- GATA4 | c.177G>A p.A59= | Silent (SNP) | VAF 391/814 reads (48%) | catalogued as rs1248717520; called by muse, mutect2, varscan2
- GOLGA3 | c.3372C>T p.L1124= | Silent (SNP) | VAF 291/655 reads (44%) | catalogued as rs371259067; called by muse, mutect2, varscan2
- GPR101 | c.1245C>T p.Y415= | Silent (SNP) | VAF 383/848 reads (45%) | called by muse, mutect2, varscan2
- GRIFIN | c.159C>T p.S53= | Silent (SNP) | VAF 186/449 reads (41%) | catalogued as rs763814089; called by muse, mutect2, varscan2
- GSX1 | c.759A>G p.S253= | Silent (SNP) | VAF 236/485 reads (49%) | catalogued as rs138515715; called by muse, mutect2, varscan2
- HRH3 | c.591C>T p.Y197= | Silent (SNP) | VAF 319/685 reads (47%) | catalogued as rs201285011, COSV58050304; called by muse, mutect2, varscan2
- IFFO1 | c.684C>T p.G228= | Silent (SNP) | VAF 241/537 reads (45%) | called by muse, mutect2, varscan2
- IGHG1 | c.657C>A p.I219= | Silent (SNP) | VAF 290/728 reads (40%) | called by muse, mutect2, varscan2
- IRX2 | c.993G>A p.S331= | Silent (SNP) | VAF 343/710 reads (48%) | catalogued as COSV57412226; called by muse, mutect2, varscan2
- JAG1 | c.1128T>C p.D376= | Silent (SNP) | VAF 159/339 reads (47%) | called by muse, mutect2, varscan2
- KBTBD13 | c.756G>A p.A252= | Silent (SNP) | VAF 404/806 reads (50%) | catalogued as rs1431328866; called by muse, mutect2, varscan2
- KIAA1109 | c.13182C>T p.S4394= | Silent (SNP) | VAF 241/544 reads (44%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1095C>T p.S365= | Silent (SNP) | VAF 281/610 reads (46%) | catalogued as rs766384876, COSV56815380; called by muse, mutect2, varscan2
- KIAA2026 | c.3447A>G p.L1149= | Silent (SNP) | VAF 195/430 reads (45%) | catalogued as rs766216619; called by muse, mutect2, varscan2
- KIF13B | c.1422G>T p.G474= | Silent (SNP) | VAF 124/251 reads (49%) | called by muse, mutect2, varscan2
- LMNTD2 | c.24C>A p.G8= | Silent (SNP) | VAF 284/636 reads (45%) | called by muse, mutect2, varscan2
- MAN2A1 | c.603A>G p.L201= | Silent (SNP) | VAF 160/370 reads (43%) | called by muse, mutect2, varscan2
- MAN2C1 | c.1833C>T p.A611= | Silent (SNP) | VAF 242/548 reads (44%) | catalogued as rs367965869; called by muse, mutect2, varscan2
- MAP3K19 | c.2031T>C p.T677= | Silent (SNP) | VAF 190/441 reads (43%) | called by muse, mutect2, varscan2
- MICAL3 | c.1131C>G p.S377= | Silent (SNP) | VAF 257/555 reads (46%) | called by muse, mutect2, varscan2
- MPST | c.807G>A p.V269= (on ENST00000341116 / NM_001369904.2; = p.V289= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 137/776 reads (18%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1083C>T p.T361= (on ENST00000374979 / NM_001308027.2; = p.T309= on NM_024631.4) | Silent (SNP) | VAF 276/583 reads (47%) | catalogued as rs753485901; called by muse, mutect2, varscan2
- NEK2 | c.1335C>T p.R445= | Silent (SNP) | VAF 178/400 reads (45%) | catalogued as COSV65356407; called by muse, mutect2
- NOTCH3 | c.1059C>T p.D353= | Silent (SNP) | VAF 216/462 reads (47%) | catalogued as rs529200949, COSV99656825; ClinVar: benign; called by muse, mutect2, varscan2
- NRDC | c.2718C>T p.G906= | Silent (SNP) | VAF 234/588 reads (40%) | catalogued as rs764657732; called by muse, mutect2, varscan2
- NYNRIN | c.3897G>A p.P1299= | Silent (SNP) | VAF 336/732 reads (46%) | catalogued as rs779187036; called by muse, mutect2, varscan2
- OBSCN | c.5247G>T p.T1749= | Silent (SNP) | VAF 367/807 reads (45%) | catalogued as COSV52806743; called by muse, mutect2, varscan2
- OTUD4 | c.1194G>A p.G398= (on ENST00000447906 / NM_001366057.1; = p.G333= on NM_001102653.1) | Silent (SNP) | VAF 18/522 reads (3%) | catalogued as rs1422727346; called by muse, mutect2
- PCDHGA5 | c.117G>T p.L39= | Silent (SNP) | VAF 275/596 reads (46%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2154C>T p.R718= | Silent (SNP) | VAF 328/702 reads (47%) | called by muse, varscan2
- PLSCR2 | c.141T>C p.H47= | Silent (SNP) | VAF 245/557 reads (44%) | called by muse, mutect2, varscan2
- PPFIA3 | c.222C>T p.L74= | Silent (SNP) | VAF 143/350 reads (41%) | called by muse, mutect2, varscan2
- PPFIA3 | c.477C>T p.L159= | Silent (SNP) | VAF 164/356 reads (46%) | catalogued as COSV100495112; called by muse, mutect2, varscan2
- PRKAG3 | c.1302C>T p.C434= | Silent (SNP) | VAF 248/545 reads (46%) | catalogued as rs868202669; called by muse, mutect2, varscan2
- PRKD2 | c.2214C>T p.G738= | Silent (SNP) | VAF 289/680 reads (43%) | catalogued as rs982819869, COSV99354333; called by muse, mutect2, varscan2
- PRSS16 | c.819G>A p.G273= | Silent (SNP) | VAF 316/719 reads (44%) | catalogued as rs370382383; called by muse, mutect2, varscan2
- PTEN | c.381A>T p.G127= | Silent (SNP) | VAF 223/503 reads (44%) | called by muse, mutect2, varscan2
- RGS14 | c.825A>G p.L275= | Silent (SNP) | VAF 175/392 reads (45%) | called by muse, mutect2, varscan2
- RNF180 | c.756T>C p.T252= | Silent (SNP) | VAF 53/442 reads (12%) | called by muse, mutect2, varscan2
- SLC19A1 | c.763C>T p.L255= | Silent (SNP) | VAF 321/727 reads (44%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2328C>T p.D776= | Silent (SNP) | VAF 243/487 reads (50%) | catalogued as rs116555814; called by muse, mutect2, varscan2
- SLC6A17 | c.432C>T p.F144= | Silent (SNP) | VAF 159/339 reads (47%) | catalogued as rs1334090420; called by muse, mutect2, varscan2
- SOBP | c.2553C>T p.S851= | Silent (SNP) | VAF 219/495 reads (44%) | called by muse, mutect2, varscan2
- SOX11 | c.831C>A p.A277= | Silent (SNP) | VAF 261/606 reads (43%) | catalogued as COSV58983858; called by muse, mutect2, varscan2
- SPNS1 | c.1530T>C p.I510= | Silent (SNP) | VAF 280/615 reads (46%) | called by muse, mutect2, varscan2
- STARD8 | c.942C>T p.H314= | Silent (SNP) | VAF 374/760 reads (49%) | catalogued as rs143103482; called by muse, mutect2, varscan2
- STK10 | c.960C>T p.D320= | Silent (SNP) | VAF 265/574 reads (46%) | catalogued as rs139075094; called by muse, mutect2, varscan2
- SYNE2 | c.879G>A p.E293= | Silent (SNP) | VAF 136/346 reads (39%) | catalogued as COSV58360947; called by muse, mutect2, varscan2
- TAF1C | c.2139A>G p.L713= | Silent (SNP) | VAF 21/733 reads (3%) | called by muse, mutect2
- TIGD7 | c.891T>C p.S297= | Silent (SNP) | VAF 213/529 reads (40%) | called by muse, mutect2, varscan2
- TLNRD1 | c.1062G>A p.P354= | Silent (SNP) | VAF 177/403 reads (44%) | catalogued as rs370704886; called by muse, mutect2, varscan2
- TPP2 | c.747C>T p.Y249= | Silent (SNP) | VAF 176/404 reads (44%) | catalogued as rs945024942, COSV65753922; called by muse, mutect2, varscan2
- TRIOBP | c.5367C>T p.D1789= (on ENST00000644935 / NM_001039141.3; = p.D76= on NM_007032.5) | Silent (SNP) | VAF 205/473 reads (43%) | catalogued as rs778567541; called by muse, varscan2
- UBE2S | c.306C>T p.D102= | Silent (SNP) | VAF 177/430 reads (41%) | called by muse, mutect2, varscan2
- VIPR2 | c.1050C>T p.S350= | Silent (SNP) | VAF 29/633 reads (5%) | called by muse, mutect2
- WRAP53 | c.867C>T p.G289= | Silent (SNP) | VAF 254/536 reads (47%) | called by muse, mutect2, varscan2
- YBX3 | c.603C>T p.S201= | Silent (SNP) | VAF 211/465 reads (45%) | catalogued as rs750604266, COSV54384800; called by muse, varscan2
- ZNF516 | c.1431G>A p.P477= | Silent (SNP) | VAF 304/634 reads (48%) | catalogued as rs1291253221, COSV101487323; called by muse, mutect2, varscan2
- ZNF638 | c.3465A>G p.T1155= | Silent (SNP) | VAF 266/627 reads (42%) | catalogued as rs370612354; called by muse, mutect2, varscan2
- ZSCAN16 | c.105C>T p.H35= | Silent (SNP) | VAF 297/615 reads (48%) | catalogued as rs1375538863; called by muse, mutect2, varscan2
- ADAM20 | c.-55T>G | 5'UTR (SNP) | VAF 273/577 reads (47%) | called by muse, mutect2, varscan2
- FHL1 | c.*64dup | 3'UTR (INS) | VAF 186/414 reads (45%) | called by mutect2, varscan2
- GRK4 | c.52+1246C>T | Intron (SNP) | VAF 212/456 reads (46%) | catalogued as rs1413682604; called by muse, varscan2
- HEPACAM2 | c.*257G>A | 3'UTR (SNP) | VAF 167/384 reads (43%) | catalogued as rs569009449; called by muse, mutect2, varscan2
- HYDIN | c.-10del | 5'UTR (DEL) | VAF 128/320 reads (40%) | catalogued as rs768899959; called by mutect2, varscan2
- LGI4 | c.794-33G>C | Intron (SNP) | VAF 440/977 reads (45%) | called by muse, mutect2, varscan2
- LINC00884 | n.1274-3780C>T | Intron (SNP) | VAF 177/402 reads (44%) | called by muse, mutect2, varscan2
- NPR3 | chr5:32710735 C>T | 5'Flank (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- OBSCN | c.11660-1004G>A | Intron (SNP) | VAF 190/407 reads (47%) | catalogued as COSV52806517; called by muse, mutect2, varscan2
- PPM1A | c.952+11dup | Intron (INS) | VAF 160/367 reads (44%) | called by mutect2, varscan2
- SPOCD1 | c.1869-116C>A | Intron (SNP) | VAF 257/617 reads (42%) | called by muse, mutect2, varscan2
- YIF1A | c.735+21del | Intron (DEL) | VAF 357/714 reads (50%) | catalogued as rs750015700; called by mutect2, varscan2
